Somatic mutation profile of tumor specimen TARGET-20-PASMGW-09A (aliquot TARGET-20-PASMGW-09A-01D) from TARGET case TARGET-20-PASMGW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,089 days).
Specimen TARGET-20-PASMGW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1dee61d0-a28c-4d18-8de6-4970c7acd566.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASMGW-14A (Bone Marrow Normal), aliquot TARGET-20-PASMGW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a90b057a-1826-4780-9dbf-3d0ad0f69e35

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 64/226 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EPHA6 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.427); catalogued as rs368808214; called by muse, mutect2, varscan2
